Somatic mutation profile of tumor specimen C3N-01495-01 (aliquot CPT0213080007) from CPTAC case C3N-01495, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen C3N-01495-01: Sample type: Primary Tumor; Tissue type: Tumor; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab48e224-1377-40f4-b1f9-dcbd87f72264.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01495-31 (Blood Derived Normal), aliquot CPT0213200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da0fb457-ef72-47fa-ac48-615d3dd934a7

The open-access MAF lists 160 somatic variants for this specimen: 107 protein-altering or splice-affecting, 47 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 47, Nonsense Mutation 5, Frame Shift Ins 2, Intron 2, RNA 1, 5'Flank 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/410 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACKR1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 175/874 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929496; called by muse, mutect2, varscan2
- ACSM2A | c.1343G>A p.G448E (on ENST00000219054; = p.G369E on NM_001308169.2) | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs751254094, COSV54584996; called by muse, mutect2, varscan2
- ACSM2B | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 48/670 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774547919, COSV61657965; called by muse, mutect2
- AOX1 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 166/473 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV65982803; called by muse, mutect2, varscan2
- ARHGEF10L | c.3262G>A p.V1088I | Missense Mutation (SNP) | VAF 126/420 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.397); catalogued as rs145857867; called by muse, mutect2, varscan2
- CACNA1I | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 222/417 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384989842; called by muse, varscan2
- CAPN11 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 91/312 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1185560491; called by muse, mutect2, varscan2
- CCNI2 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 192/327 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs981740825; called by muse, mutect2, varscan2
- CFHR2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as COSV66380777; called by muse, mutect2, varscan2
- COL4A4 | c.3787C>T p.Q1263* | Nonsense Mutation (SNP) | VAF 97/313 reads (31%) | catalogued as COSV61632295; called by muse, mutect2, varscan2
- CROCC | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 95/544 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as rs1166682356; called by muse, mutect2, varscan2
- CRYBG3 | c.3482C>T p.A1161V | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1221179300; called by muse, mutect2, varscan2
- CYP2R1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 95/289 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100584958; called by muse, mutect2, varscan2
- DNAH3 | c.6703G>A p.G2235R | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1284196365; called by muse, mutect2, varscan2
- EPHA6 | c.1912G>A p.E638K (on ENST00000389672 / NM_001080448.3; = p.E30K on NM_173655.4) | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV101061981; called by muse, mutect2, varscan2
- ERICH3 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 139/425 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751032690, COSV58619044; called by muse, mutect2, varscan2
- EXO1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 152/461 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs867711669; called by muse, mutect2, varscan2
- FBLN2 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 156/455 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55489230; called by muse, varscan2
- GDAP2 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1398219552; called by muse, mutect2, varscan2
- GRM5 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59614690; called by muse, mutect2, varscan2
- IRAG1 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs373767088, COSV70212975; called by muse, mutect2, varscan2
- KRT4 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs755363361, CM092718; called by muse, mutect2, varscan2
- KRTAP10-4 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 88/784 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100553966; called by muse, mutect2, varscan2
- LRFN2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1416327539; called by muse, mutect2, varscan2
- LVRN | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63495922; called by muse, mutect2, varscan2
- MALRD1 | c.4159C>T p.H1387Y | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1488845394; called by muse, mutect2, varscan2
- MCHR2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs770957970, COSV56000747; called by muse, mutect2, varscan2
- MKX | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 201/482 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101008856; called by muse, mutect2, varscan2
- MPO | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 146/413 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs762653317; called by muse, mutect2, varscan2
- MUC16 | c.10697G>A p.S3566N | Missense Mutation (SNP) | VAF 346/815 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV101200824; called by muse, mutect2
- MUC17 | c.6265G>A p.G2089S | Missense Mutation (SNP) | VAF 145/596 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1296972084; called by muse, mutect2, varscan2
- NEFM | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 162/628 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV55334268; called by muse, mutect2, varscan2
- NONO | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 178/322 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV52140673; called by muse, mutect2, varscan2
- NTRK2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs1408094711, COSV52867840; called by muse, mutect2, varscan2
- OR2A2 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 287/658 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs1043911058, COSV68871344, COSV68871799; called by muse, mutect2, varscan2
- OR2C3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 136/424 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as rs1339478863, COSV63575607; called by muse, mutect2, varscan2
- OR4N2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 145/378 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV100269469, COSV60051361; called by muse, mutect2, varscan2
- PHF3 | c.3020C>T p.P1007L | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.367); catalogued as COSV50348246; called by muse, mutect2, varscan2
- PLCH1 | c.2374G>A p.E792K (on ENST00000340059 / NM_001130960.2; = p.E804K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780182537, COSV100397543; called by muse, mutect2, varscan2
- PPA1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104428036; called by muse, mutect2, varscan2
- PPRC1 | c.1790T>C p.V597A | Missense Mutation (SNP) | VAF 224/545 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs977809063; called by muse, mutect2, varscan2
- PTCHD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59776225; called by muse, mutect2, varscan2
- SLC45A2 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 276/407 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56872610; called by muse, mutect2, varscan2
- TCHHL1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 120/649 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs866241507, COSV64286720; called by muse, mutect2, varscan2
- TLR4 | c.1135G>A p.D379N (on ENST00000355622 / NM_138554.5; = p.D339N on NM_003266.4) | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62924461; called by muse, mutect2, varscan2
- TNFAIP3 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 174/480 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs1430601409, COSV52799603; called by muse, mutect2, varscan2
- TNNI3K | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.996); catalogued as rs971911939, COSV53947677, COSV53949680; called by muse, mutect2, varscan2
- TRHDE | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs923804375; called by muse, mutect2, varscan2
- UBN2 | c.2287C>T p.H763Y | Missense Mutation (SNP) | VAF 184/447 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1185851982; called by muse, mutect2, varscan2
- USP49 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 193/499 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as rs866320380; called by muse, mutect2, varscan2
- ZNF226 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs766519729, COSV56197233; called by muse, mutect2, varscan2
- ZNF695 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100377327; called by muse, mutect2, varscan2
- ZNF835 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 306/443 reads (69%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.306); catalogued as COSV73379166; called by muse, mutect2, varscan2
- ADAMTS13 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 156/442 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADPRHL1 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 211/728 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ANKRD46 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 328/652 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATL3 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C10orf71 | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 317/688 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- C2orf73 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CACHD1 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 328/639 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CBLB | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNI2 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 192/329 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHL1 | c.2246T>G p.V749G (on ENST00000397491 / NM_001253387.1; = p.V765G on NM_006614.4) | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL4A6 | c.4936T>A p.F1646I | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CTAGE8 | c.1928G>A p.R643K | Missense Mutation (SNP) | VAF 62/1014 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, varscan2
- CTNNA3 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCTN1 | c.3716A>G p.Q1239R | Missense Mutation (SNP) | VAF 114/293 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND3 | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 261/503 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH10 | c.5929C>T p.Q1977* (on ENST00000409039; = p.Q1916* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 99/159 reads (62%) | called by muse, mutect2, varscan2
- DTYMK | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 141/456 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELOA3C | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 129/5162 reads (2%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- EPHA3 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GAGE2E | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 58/1094 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- GIMAP1-GIMAP5 | c.476T>A p.V159E | Missense Mutation (SNP) | VAF 325/760 reads (43%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRB10 | c.917C>T p.S306L (on ENST00000398812; = p.S248L on NM_001001550.3) | Missense Mutation (SNP) | VAF 291/720 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- GRIK2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDGFL2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 464/1170 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- HELZ2 | c.4106C>T p.A1369V (on ENST00000467148 / NM_001037335.2; = p.A800V on NM_033405.3) | Missense Mutation (SNP) | VAF 149/400 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IFIT1 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IMPG1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 241/435 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- IPP | c.1539G>A p.W513* | Nonsense Mutation (SNP) | VAF 83/241 reads (34%) | called by muse, mutect2, varscan2
- ITPKB | c.1156dup p.E386Gfs*3 | Frame Shift Ins (INS) | VAF 176/556 reads (32%) | called by mutect2, pindel, varscan2
- KRTAP10-6 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, varscan2
- LAMB1 | c.1688A>T p.N563I | Missense Mutation (SNP) | VAF 165/369 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORF4L1 | c.758T>C p.V253A (on ENST00000331268 / NM_206839.2; = p.V214A on NM_006791.4) | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NBEA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NOTCH4 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 644/1039 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NRXN2 | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by mutect2, varscan2
- OR4K5 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- PDE10A | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 79/268 reads (29%) | called by muse, mutect2, varscan2
- POLR3GL | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 459/783 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PPP1R16B | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 141/711 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PRSS35 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 145/399 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PRSS36 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PTPRQ | c.6712G>A p.G2238R (on ENST00000616559; = p.G2205R on NM_001145026.2) | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS1 | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 118/415 reads (28%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ROR2 | c.2762C>A p.P921Q | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- ROR2 | c.1457A>T p.K486I | Missense Mutation (SNP) | VAF 133/417 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCART1 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGCE | c.455G>T p.G152V (on ENST00000647096; = p.G116V on NM_003919.3) | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3RF3 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 141/383 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SORL1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 135/451 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPTAN1 | c.6692+1dup | Frame Shift Ins (INS) | VAF 112/401 reads (28%) | called by mutect2, pindel, varscan2
- TRAV8-7 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2
- ZBTB2 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 98/298 reads (33%) | called by muse, mutect2, varscan2
- ABL2 | c.2013C>T p.S671= (on ENST00000502732 / NM_007314.4; = p.S656= on NM_005158.5) | Silent (SNP) | VAF 176/535 reads (33%) | catalogued as COSV61010854, COSV61014653; called by muse, mutect2, varscan2
- ACTG2 | c.570C>T p.L190= | Silent (SNP) | VAF 100/373 reads (27%) | catalogued as rs1468448437; called by muse, mutect2, varscan2
- ANHX | c.1005C>A p.P335= | Silent (SNP) | VAF 31/600 reads (5%) | called by muse, mutect2
- ARMH2 | c.624G>A p.E208= | Silent (SNP) | VAF 112/551 reads (20%) | called by muse, mutect2, varscan2
- ASPH | c.2166C>T p.S722= | Silent (SNP) | VAF 237/484 reads (49%) | catalogued as rs867671728; called by muse, mutect2, varscan2
- BPIFB1 | c.402G>T p.T134= | Silent (SNP) | VAF 38/871 reads (4%) | catalogued as rs140657571, COSV53605147; called by muse, mutect2
- CACNB2 | c.579G>A p.G193= (on ENST00000324631 / NM_201596.3; = p.G138= on NM_000724.4) | Silent (SNP) | VAF 71/320 reads (22%) | catalogued as rs780755312, COSV56633147, COSV56646527; called by muse, mutect2, varscan2
- CPED1 | c.771T>C p.A257= | Silent (SNP) | VAF 105/494 reads (21%) | called by muse, mutect2, varscan2
- DDX54 | c.1839G>A p.E613= | Silent (SNP) | VAF 176/472 reads (37%) | catalogued as rs1434425369; called by muse, varscan2
- DMXL2 | c.5389C>T p.L1797= | Silent (SNP) | VAF 116/439 reads (26%) | catalogued as rs113771652; called by muse, mutect2, varscan2
- DMXL2 | c.5388C>T p.F1796= | Silent (SNP) | VAF 116/437 reads (27%) | called by muse, mutect2, varscan2
- DOK2 | c.111C>T p.A37= | Silent (SNP) | VAF 287/536 reads (54%) | catalogued as rs1365929267; called by muse, mutect2, varscan2
- DSC1 | c.360G>A p.K120= | Silent (SNP) | VAF 77/254 reads (30%) | called by muse, mutect2, varscan2
- ELFN1 | c.672C>T p.P224= | Silent (SNP) | VAF 372/1376 reads (27%) | catalogued as rs372638912; called by muse, varscan2
- F2R | c.561C>T p.Y187= | Silent (SNP) | VAF 149/280 reads (53%) | catalogued as rs781662568, COSV59930201; called by muse, mutect2, varscan2
- FLG2 | c.1827T>C p.H609= | Silent (SNP) | VAF 524/755 reads (69%) | catalogued as rs1269080969; called by muse, mutect2, varscan2
- HIF3A | c.1632G>A p.G544= (on ENST00000377670 / NM_152795.4; = p.G475= on NM_022462.4) | Silent (SNP) | VAF 186/522 reads (36%) | catalogued as rs369380972; called by muse, mutect2, varscan2
- IGDCC4 | c.1062C>T p.F354= | Silent (SNP) | VAF 182/445 reads (41%) | catalogued as rs1033134454; called by muse, mutect2, varscan2
- IGSF9 | c.759C>T p.Y253= | Silent (SNP) | VAF 478/820 reads (58%) | catalogued as COSV63642577; called by muse, mutect2, varscan2
- INTS1 | c.2229C>T p.V743= | Silent (SNP) | VAF 128/681 reads (19%) | catalogued as rs761560711, COSV101248250; called by muse, mutect2, varscan2
- KNDC1 | c.4390C>T p.L1464= | Silent (SNP) | VAF 167/442 reads (38%) | catalogued as COSV100462866; called by muse, mutect2, varscan2
- KRTAP13-2 | c.243C>T p.Y81= | Silent (SNP) | VAF 153/477 reads (32%) | catalogued as rs756813722, COSV101299623, COSV67761924; called by muse, mutect2, varscan2
- L1TD1 | c.2286G>A p.V762= | Silent (SNP) | VAF 91/299 reads (30%) | catalogued as rs1205241808; called by muse, mutect2, varscan2
- LARP6 | c.1350G>A p.T450= | Silent (SNP) | VAF 140/431 reads (32%) | catalogued as rs1444605263; called by muse, mutect2, varscan2
- LRFN2 | c.60C>T p.A20= | Silent (SNP) | VAF 144/413 reads (35%) | called by muse, mutect2, varscan2
- MARCHF10 | c.2415C>T p.S805= | Silent (SNP) | VAF 104/308 reads (34%) | catalogued as COSV60888800; called by muse, mutect2, varscan2
- MET | c.2055G>A p.G685= | Silent (SNP) | VAF 131/555 reads (24%) | catalogued as rs766401668, COSV59267302; called by muse, mutect2, varscan2
- MGAM | c.4236G>A p.L1412= | Silent (SNP) | VAF 77/422 reads (18%) | catalogued as COSV101527587; called by muse, mutect2, varscan2
- NEU3 | c.136C>T p.L46= | Silent (SNP) | VAF 109/352 reads (31%) | called by muse, mutect2, varscan2
- ORAI1 | c.561C>T p.F187= | Silent (SNP) | VAF 140/238 reads (59%) | catalogued as rs782419547; called by muse, mutect2, varscan2
- PFKFB2 | c.1107G>T p.L369= | Silent (SNP) | VAF 9/220 reads (4%) | called by muse, mutect2
- PREB | c.1083C>T p.L361= | Silent (SNP) | VAF 177/481 reads (37%) | called by muse, mutect2, varscan2
- PROS1 | c.213C>T p.V71= | Silent (SNP) | VAF 77/283 reads (27%) | catalogued as COSV62399035; called by muse, mutect2, varscan2
- PTGFRN | c.1491G>A p.T497= | Silent (SNP) | VAF 131/394 reads (33%) | catalogued as rs770023214, COSV67798639; called by muse, mutect2, varscan2
- SCN1A | c.3387G>A p.T1129= (on ENST00000303395 / NM_001202435.3; = p.T1118= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/218 reads (31%) | catalogued as rs375953445; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- STARD13 | c.2151C>T p.F717= (on ENST00000336934 / NM_001243476.3; = p.F599= on NM_052851.3) | Silent (SNP) | VAF 172/569 reads (30%) | catalogued as rs758628937; called by muse, mutect2, varscan2
- STK10 | c.2205C>T p.L735= | Silent (SNP) | VAF 89/169 reads (53%) | called by muse, mutect2, varscan2
- SULT2B1 | c.819C>T p.L273= (on ENST00000201586 / NM_177973.2; = p.L258= on NM_004605.2) | Silent (SNP) | VAF 177/260 reads (68%) | catalogued as COSV52377924; called by muse, mutect2, varscan2
- TAF11L12 | c.240G>A p.K80= | Silent (SNP) | VAF 272/372 reads (73%) | called by muse, mutect2, varscan2
- TM9SF2 | c.1779C>T p.F593= | Silent (SNP) | VAF 91/372 reads (24%) | catalogued as COSV100899720; called by muse, mutect2, varscan2
- TMEM132C | c.372G>A p.K124= | Silent (SNP) | VAF 142/371 reads (38%) | catalogued as rs781781783, COSV70672774; called by muse, mutect2, varscan2
- TNFSF14 | c.87G>A p.R29= | Silent (SNP) | VAF 329/753 reads (44%) | catalogued as rs770323762, COSV55590671; called by muse, mutect2, varscan2
- TRBV4-1 | c.150T>A p.A50= | Silent (SNP) | VAF 78/420 reads (19%) | called by muse, mutect2, varscan2
- TRMT2B | c.895C>T p.L299= | Silent (SNP) | VAF 158/312 reads (51%) | called by muse, mutect2, varscan2
- WEE2 | c.1239C>A p.P413= | Silent (SNP) | VAF 102/567 reads (18%) | called by muse, mutect2, varscan2
- ZNF718 | c.873C>T p.A291= | Silent (SNP) | VAF 337/451 reads (75%) | catalogued as rs782032896; called by muse, mutect2, varscan2
- ZNF728 | c.39C>T p.F13= | Silent (SNP) | VAF 168/436 reads (39%) | catalogued as COSV74099464; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826253 C>T | 3'Flank (SNP) | VAF 88/171 reads (51%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-108-22C>A | Intron (SNP) | VAF 91/304 reads (30%) | called by muse, mutect2, varscan2
- DUSP22 | c.508+102G>C | Intron (SNP) | VAF 103/394 reads (26%) | called by muse, mutect2, varscan2
- LINC02363 | n.920C>T | RNA (SNP) | VAF 298/427 reads (70%) | catalogued as rs999277667; called by muse, mutect2, varscan2
- NOL12 | c.*1134C>T | 3'UTR (SNP) | VAF 81/302 reads (27%) | called by muse, mutect2, varscan2
- SKOR1 | chr15:67824797 C>T | 5'Flank (SNP) | VAF 162/455 reads (36%) | called by muse, mutect2, varscan2
